Surgical pathology report (de-identified scan), TCGA case TCGA-78-7633, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7633-01A (Primary Tumor).

[page 1 of 2]
SEE SUPPLEMENTARY REPORT BELOW

HISTORY

Adenocarcinoma.

MACROSCOPIC

Two specimens submitted.

1: The first specimen is labelled 'left upper lobe' and consists of a lobe of lung measuring 200 x 80 x 20 mm in the fresh state. Overlying the apex and the lateral aspect of the apex of the lobe is an area of pleural tethering with an underlying tumour mass. The remainder of the pleural surface shows no specific abnormality apart from extensive carbon pigmentation. The lobar bronchus has been transected flush with the hilar soft tissue and has two lumens at this point. Small peribronchial anthracotic nodes are noted, none of which appears macroscopically to be involved by a tumour. Sectioning reveals an apical tumour mass which appears to be bilobed. The combined maximum size of this lesion is 32 mm. The more superior lobule is approximately 20 mm in diameter and shows foci of central necrosis. The more lateral and inferior lesion is approximately 12 mm in diameter and has a solid cream to tan cut surface. In some areas the lobules appear to be separated by 2 to 3 mm of unremarkable lung parenchyma. Both lobules abut the overlying pleura. No other lesions are identified on serial slicing through the parenchyma. However there is severe emphysema. [1A, bronchial resection margin; 1B, peribronchial lymph nodes; 1C-1D longitudinal sections through tumour including overlying pleura and both lobules; 1E, sections of inferolateral solid nodule with overlying pleura; 1F, uninvolved lung parenchyma.]

2: The second specimen is labelled 'left hilar lymph node' and consists of three fragments of focally anthracotic and fatty tissue. [BIT, 2A.]

MICROSCOPY

1: Sections show two adenocarcinomas. The first has a predominantly acinar architecture with a small amount of surrounding bronchioloalveolar type growth. Extensive blood vessel invasion is noted and there is possible lymphatic permeation. The other lesion is a papillary adenocarcinoma. The lesions are separated by approximately 5 mm by unremarkable lung. A third focus of adenocarcinoma with a bronchioloalveolar pattern is present within the random section of lung. This measures 5 mm in diameter. Overlying both tumours, there is scarring of the pleura and features suspicious for invasion. Special stains will be performed. No perineural permeation is identified. The lesion is well clear of the bronchial resection margin. No lymph node metastases are seen. The uninvolved lung shows evidence of emphysema.

2: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

SUMMARY

1-2: Left upper lobe and left hilar lymph nodes:

A: Three foci of moderately differentiated adenocarcinoma; 20 mm (acinar), 12 mm (papillary) and 5 mm (bronchioloalveolar) in maximal dimension.

B: Extensive blood vessel invasion; probable lymphatic permeation but no perineural permeation present.

C: Possible pleural invasion identified; special stains being performed; clear of bronchial margin.

D: No lymph node metastases.

E: T1N0 (awaiting pleural stains)

F: Non-neoplastic lung: Mild emphysema.

[page 2 of 2]
SUPPLEMENTARY REPORT

1: Tumour invades into the visceral pleura overlying the tumour with the acinar architecture. It is not definitely on the pleural surface. There is no invasion of the visceral pleura by the papillary carcinoma. Both tumours stain positively for CK 7 and TTF 1. CK 20 is negative. This indicates both lesions are pulmonary in origin but considering their different architecture as they appear to represent synchronous tumours.

SUMMARY

1-2: Left upper lobe and left hilar lymph nodes:

A: Three foci of moderately differentiated adenocarcinoma; 20 mm (acinar), 12 mm (papillary) and 5 mm (bronchioloalveolar) in maximal dimension.

B: Extensive blood vessel invasion; probable lymphatic permeation but no perineural permeation present.

C: Visceral pleural invasion identified overlying the acinar pattern carcinoma; clear of bronchial margin.

D: No lymph node metastases.

E: T2 N0 (acinar pattern carcinoma) T1N0 (papillary and bronchioloalveolar pattern carcinomas)

F: Non-neoplastic lung; Mild emphysema.

T-28000 M-81403 P1-03000

Source: NCI Genomic Data Commons file 2862257b-056d-497b-912a-e8d3fe664343 (TCGA-78-7633.B1031A29-F3AF-4F4F-A3D2-1BE59C524222.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).